Somatic mutation profile of tumor specimen TCGA-4L-AA1F-01A (aliquot TCGA-4L-AA1F-01A-11D-A41K-08) from TCGA case TCGA-4L-AA1F, project TCGA-PRAD (Prostate Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Prostate gland; Age at diagnosis: 64.8 years (23,665 days).
Specimen TCGA-4L-AA1F-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) c7bb6e83-fe44-472a-aea0-2fbbc763c18a.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-4L-AA1F-10A (Blood Derived Normal), aliquot TCGA-4L-AA1F-10A-01D-A41N-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/26f7f91e-40d0-414f-9a0c-3a7183514d96

The open-access MAF lists 28 somatic variants for this specimen: 21 protein-altering or splice-affecting, 6 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 14, Silent 6, Nonsense Mutation 5, Frame Shift Del 2, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- APOBEC3B | c.488A>G p.N163S | Missense Mutation (SNP) | VAF 39/182 reads (21%) | SIFT tolerated (0.19); PolyPhen benign (0.078); catalogued as rs758686056, COSV100213654; called by muse, mutect2, varscan2
- ASTN1 | c.3334C>T p.R1112* | Nonsense Mutation (SNP) | VAF 8/49 reads (16%) | catalogued as rs199961480; called by muse, mutect2, varscan2
- CWF19L1 | c.1543A>T p.K515* | Nonsense Mutation (SNP) | VAF 9/74 reads (12%) | catalogued as COSV100821444; called by muse, mutect2
- CWF19L1 | c.1541G>A p.S514N | Missense Mutation (SNP) | VAF 9/75 reads (12%) | SIFT tolerated (0.16); PolyPhen benign (0.145); catalogued as COSV100821445; called by muse, mutect2
- DMRT1 | c.910G>A p.V304M | Missense Mutation (SNP) | VAF 10/41 reads (24%) | SIFT tolerated (0.2); PolyPhen benign (0.009); catalogued as rs141672484; called by muse, mutect2, varscan2
- F2R | c.563C>T p.A188V | Missense Mutation (SNP) | VAF 13/151 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.9); catalogued as rs770087836, COSV100058299; called by muse, mutect2
- FSHR | c.1670G>A p.R557Q | Missense Mutation (SNP) | VAF 4/33 reads (12%) | SIFT tolerated (0.3); PolyPhen probably damaging (1); catalogued as rs150235567; called by muse, mutect2
- INSRR | c.863G>C p.G288A | Missense Mutation (SNP) | VAF 8/32 reads (25%) | SIFT tolerated (0.53); PolyPhen benign (0.197); catalogued as COSV100947134; called by muse, mutect2, varscan2
- KDM2B | c.2939A>C p.E980A | Missense Mutation (SNP) | VAF 12/34 reads (35%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.057); catalogued as COSV100997172; called by muse, mutect2, varscan2
- LRRK2 | c.7513C>A p.Q2505K | Missense Mutation (SNP) | VAF 9/87 reads (10%) | SIFT tolerated (0.63); PolyPhen benign (0.018); catalogued as rs753832208, COSV100109191; called by muse, mutect2
- MYO3A | c.2950C>T p.R984* | Nonsense Mutation (SNP) | VAF 25/103 reads (24%) | catalogued as rs759428208, COSV56322147; called by muse, mutect2, varscan2
- NET1 | c.327A>C p.R109S (on ENST00000355029 / NM_001047160.3; = p.R55S on NM_005863.5) | Missense Mutation (SNP) | VAF 16/130 reads (12%) | SIFT deleterious (0); PolyPhen benign (0.065); catalogued as COSV100742204; called by muse, mutect2, varscan2
- PPP2CA | c.269G>A p.G90E | Missense Mutation (SNP) | VAF 11/50 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99196021; called by muse, mutect2, varscan2
- SLC22A14 | c.844G>T p.G282W | Missense Mutation (SNP) | VAF 14/131 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1696551, COSV99828088; called by muse, mutect2, varscan2
- SSX7 | c.130G>T p.E44* | Nonsense Mutation (SNP) | VAF 31/96 reads (32%) | catalogued as COSV99993705; called by muse, mutect2, varscan2
- TENM2 | c.1879G>A p.G627S (on ENST00000518659 / NM_001122679.2; = p.G395S on NM_001080428.3) | Missense Mutation (SNP) | VAF 37/140 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs747612752, COSV69131138; called by muse, mutect2, varscan2
- ULBP1 | c.310C>T p.Q104* | Nonsense Mutation (SNP) | VAF 17/84 reads (20%) | catalogued as rs1195938718, COSV99998000; called by muse, mutect2, varscan2
- ZBTB49 | c.1430A>G p.K477R | Missense Mutation (SNP) | VAF 7/47 reads (15%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.959); catalogued as COSV100552348; called by muse, mutect2, varscan2
- H2AC13 | c.244C>T p.R82C | Missense Mutation (SNP) | VAF 5/81 reads (6%) | SIFT deleterious, low confidence (0.03); PolyPhen possibly damaging (0.819); called by muse, mutect2
- LRIG1 | c.2366del p.D789Vfs*5 | Frame Shift Del (DEL) | VAF 32/135 reads (24%) | called by mutect2, pindel, varscan2
- PTEN | c.954_955del p.T319Ffs*5 | Frame Shift Del (DEL) | VAF 11/102 reads (11%) | called by mutect2, pindel, varscan2
- DCAF12L1 | c.844T>C p.L282= | Silent (SNP) | VAF 14/32 reads (44%) | catalogued as rs747418903, COSV100948082; called by muse, varscan2
- G2E3 | c.558C>T p.F186= | Silent (SNP) | VAF 18/145 reads (12%) | catalogued as COSV99249299; called by muse, mutect2, varscan2
- GAREM1 | c.786C>T p.L262= | Silent (SNP) | VAF 5/62 reads (8%) | catalogued as rs1339299377, COSV99330185; called by muse, mutect2
- LRRIQ1 | c.3909G>A p.K1303= | Silent (SNP) | VAF 13/194 reads (7%) | catalogued as COSV101279503, COSV101279716; called by muse, mutect2
- RFPL4B | c.654C>A p.I218= | Silent (SNP) | VAF 9/57 reads (16%) | catalogued as rs577059806, COSV101480654; called by muse, mutect2, varscan2
- SNX16 | c.651G>T p.P217= | Silent (SNP) | VAF 8/49 reads (16%) | catalogued as COSV100629475; called by muse, mutect2, varscan2
- KLK3 | c.631-349_631-348del | Intron (DEL) | VAF 12/62 reads (19%) | called by pindel, varscan2
